Somatic mutation profile of tumor specimen 0DR3ME from CCDI case PBCFZD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Clear cell meningioma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.5 years (5,662 days).
Specimen 0DR3ME: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed8847b6-29f6-4ff2-964e-52ee43bcd4c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR3L5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5effbb61-9db1-49ed-b996-fc874f46546f

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 4, Splice Region 1, Intron 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDOST | c.77C>T p.A26V (on ENST00000415136; = p.A9V on NM_005216.5) | Missense Mutation (SNP) | VAF 123/313 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV56121726; called by muse, mutect2, varscan2
- HECTD1 | c.1156+6A>C | Splice Region (SNP) | VAF 16/72 reads (22%) | catalogued as rs1194433876; called by muse, mutect2, varscan2
- MIS18A | c.111A>C p.E37D | Missense Mutation (SNP) | VAF 99/263 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MYO5C | c.1727_1746del p.E576Vfs*25 | Frame Shift Del (DEL) | VAF 48/232 reads (21%) | called by mutect2, pindel, varscan2
- PPP1R3G | c.793G>T p.A265S | Missense Mutation (SNP) | VAF 17/251 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2
- PSMC5 | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 64/193 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- SMARCE1 | c.883C>T p.Q295* | Nonsense Mutation (SNP) | VAF 163/432 reads (38%) | called by muse, mutect2, varscan2
- EPHA10 | c.780C>T p.G260= | Silent (SNP) | VAF 8/234 reads (3%) | catalogued as rs1370581042, COSV100140186; called by muse, mutect2
- SAMD15 | c.519G>A p.G173= | Silent (SNP) | VAF 57/152 reads (38%) | catalogued as rs1431065498; called by muse, mutect2, varscan2
- VRTN | c.1536C>A p.R512= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as COSV56443545; called by muse, mutect2, varscan2
- VWC2L | c.399A>T p.P133= | Silent (SNP) | VAF 137/324 reads (42%) | catalogued as rs903631012; called by muse, mutect2, varscan2
- LPCAT4 | c.478+58G>A | Intron (SNP) | VAF 24/69 reads (35%) | called by muse, varscan2
